TCGA case TCGA-16-1048 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Toronto Western Hospital.
https://portal.gdc.cancer.gov/cases/3eeaaef5-a3b2-478c-a88d-fc5d7342bbe1

Demographics
Country of residence at enrollment: Canada.

Diagnoses (1)
1. Primary (histology not recorded by GDC).
   Pathology details: Consistent pathology review: Yes.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-16-1048-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.3; Intermediate dimension: 0.3; Shortest dimension: 0.3.
  Slide TCGA-16-1048-01B-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-16-1048-01B-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 100.
- Sample TCGA-16-1048-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-16-1048-01B-01D-1224-01): tumor purity 0.67, ploidy 2.02, whole-genome doublings 0.
